Gene-level copy-number profile of tumor specimen ALCH-B37R-TTP1-A from ALCHEMIST case ALCH-B37R, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 72.7 years (26,540 days).
Specimen ALCH-B37R-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a603d4df-e7c2-4f54-81c8-fa647e54e9a7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B37R-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,721 have no estimate.
https://portal.gdc.cancer.gov/files/100e1329-3b3c-4d3a-848d-a960ee1c3a14

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 31; copy number 1: 3,646; copy number 2: 55,189; copy number 3: 10; copy number 4: 18; copy number 5: 6; copy number 6: 1; copy number 9: 1.

Homozygous deletions (total copy number 0; autosomes only): 31 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:20,692,734–20,694,013, 1 gene (within-gene range 0–1): AL663074.2.
- chr2:232,368,576–232,368,697, 1 gene: AC068134.3.
- chr3:50,419,781–50,419,899, 1 gene (within-gene range 0–1): RNA5SP131.
- chr8:139,911,238–139,933,942, 2 genes (within-gene range 0–2): AC021744.1, C8orf17.
- chr9:137,084,946–137,086,817, 1 gene: MAN1B1-DT.
- chr11:32,435,738–32,439,206, 4 genes (within-gene range 0–2): AL049692.6, AL049692.1, AL049692.5, AL049692.3.
- chr14:100,814,491–100,814,574, 1 gene (within-gene range 0–2): MIR2392.
- chr15:25,189,414–25,193,402, 3 genes (within-gene range 0–2): SNORD115-11, SNORD115-12, SNORD115-13.
- chr15:25,208,083–25,220,578, 7 genes (within-gene range 0–2): SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27.
- chr15:25,241,746–25,250,940, 6 genes (within-gene range 0–2): SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr15:90,930,180–90,955,225, 2 genes (within-gene range 0–2): UNC45A, RCCD1-AS1.
- chr16:1,111,627–1,113,399, 1 gene: AL031598.1.
- chr17:46,762,506–46,833,154, 1 gene: WNT3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:137,030,174–137,040,436, 2 genes, copy number 5 (within-gene range 2–11): FUT7, AL807752.6.
- chr9:137,057,663–137,062,461, 1 gene, copy number 5 (within-gene range 4–5): AL807752.2.
- chr14:105,489,855–105,499,575, 1 gene, copy number 9 (within-gene range 2–9): TEDC1.
- chr14:105,620,506–105,626,066, 2 genes, copy number 5–6: IGHG4, MIR8071-1.
- chr16:1,088,226–1,105,461, 2 genes, copy number 5: C1QTNF8, AL031713.1.

Autosomal genes at a single copy (total copy number 1): 790. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
